Somatic mutation profile of tumor specimen 0DWKH0 from CCDI case PBCNXC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 14.9 years (5,443 days).
Specimen 0DWKH0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9951d6f-2267-4a02-9c12-3af428c285ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWKFZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbf3e108-c07f-4b17-a696-0c12c4f56f9e

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOX8 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 93/371 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs767333361; called by muse, mutect2, varscan2
- ZAN | c.5101G>A p.D1701N | Missense Mutation (SNP) | VAF 204/860 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1274707074, COSV61813195; called by muse, mutect2, varscan2
- PREP | c.1015G>C p.G339R (on ENST00000369110; = p.G405R on NM_002726.5) | Missense Mutation (SNP) | VAF 43/427 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PSMC4 | c.919-8A>C | Splice Region (SNP) | VAF 7/252 reads (3%) | called by muse, mutect2
